Somatic mutation profile of tumor specimen TCGA-D9-A149-06A (aliquot TCGA-D9-A149-06A-11D-A196-08) from TCGA case TCGA-D9-A149, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D9-A149-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca3c30ca-e0ed-4af4-9aa3-34fc030e2163.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A149-10A (Blood Derived Normal), aliquot TCGA-D9-A149-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c60958f-7fc2-47c7-8d82-bbced14ba408

The open-access MAF lists 282 somatic variants for this specimen: 189 protein-altering or splice-affecting, 84 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 84, Nonsense Mutation 12, Splice Region 8, Intron 6, RNA 3, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FRMD4B | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV68328045; called by muse, mutect2, varscan2
- IDH1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 136/222 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1612+1G>A p.X538_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as rs773018554, COSV52197728; called by muse, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ACSM4 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV68067346; called by muse, mutect2, varscan2
- ADAM12 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as rs747876345, COSV64104298; called by muse, mutect2, varscan2
- ADAMTS5 | c.2612G>A p.G871E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1180480267, COSV53177357, COSV53178765; called by muse, mutect2, varscan2
- ADGRV1 | c.12686C>T p.P4229L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV67981929; called by muse, mutect2, varscan2
- AFF1 | c.2946G>A p.T982= | Splice Region (SNP) | VAF 28/64 reads (44%) | catalogued as rs774811579, COSV100320962, COSV57118382; called by muse, varscan2
- AGBL1 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750108622, COSV66849667; called by muse, mutect2, varscan2
- AHNAK | c.10723C>T p.P3575S | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV57208583; called by muse, mutect2, varscan2
- AHNAK | c.7799C>T p.S2600F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57208598, COSV57232904; called by muse, mutect2, varscan2
- AKAP13 | c.7582C>T p.L2528F (on ENST00000394518 / NM_007200.5; = p.L2532F on NM_006738.6) | Missense Mutation (SNP) | VAF 90/124 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222923297, COSV63452515; called by muse, mutect2, varscan2
- AKR1A1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV61086155; called by muse, mutect2, varscan2
- ALK | c.3806G>A p.G1269E | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66557991, COSV66562804; called by muse, mutect2, varscan2
- ANKMY1 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56031828; called by muse, mutect2, varscan2
- ANKRD30A | c.1411G>A p.E471K (on ENST00000611781; = p.E415K on NM_052997.2) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.341); catalogued as rs267602479, COSV64607290; called by muse, varscan2
- ANKRD42 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs929424767, COSV52615121; called by muse, mutect2, varscan2
- ARHGAP21 | c.4963C>T p.R1655* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs772723167, COSV57604071; called by mutect2, varscan2
- ARHGAP25 | c.316G>A p.E106K (on ENST00000409202 / NM_001007231.3; = p.E99K on NM_014882.3) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54900547; called by muse, mutect2, varscan2
- B4GALNT4 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs887910167; called by mutect2, varscan2
- BCL9 | c.3073T>A p.Y1025N | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52342488; called by muse, mutect2, varscan2
- BRF1 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527645; called by muse, mutect2, varscan2
- BTK | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV58118373; called by muse, mutect2, varscan2
- BTNL8 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99180600; called by muse, mutect2, varscan2
- CACNA1A | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.447); catalogued as COSV64193815, COSV64200248; called by muse, mutect2, varscan2
- CACNA1D | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860458; called by muse, mutect2, varscan2
- CACNA1D | c.765C>T p.P255= | Splice Region (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99860462; called by mutect2, varscan2
- CADM2 | c.884G>A p.R295Q (on ENST00000407528 / NM_001167674.2; = p.R297Q on NM_153184.4) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs745873421, COSV67364782; called by muse, mutect2, varscan2
- CCDC178 | c.210G>A p.G70= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as rs1042102476, COSV55766532; called by muse, mutect2, varscan2
- CCDC74B | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV60101353; called by muse, mutect2, varscan2
- CELSR2 | c.6919C>T p.R2307C | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs1366132430, COSV54768919; called by muse, mutect2, varscan2
- CFAP54 | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV61570915; called by muse, mutect2, varscan2
- CFAP58 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV63833454; called by muse, mutect2, varscan2
- CHD8 | c.6043C>T p.Q2015* (on ENST00000646647 / NM_001170629.2; = p.Q1736* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs1555313293, COSV63036603; called by muse, mutect2, varscan2
- CHRNA3 | c.1404G>A p.W468* | Nonsense Mutation (SNP) | VAF 71/101 reads (70%) | catalogued as rs1268778312, COSV55138046; called by muse, mutect2, varscan2
- CLDN22 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100033050; called by muse, mutect2, varscan2
- CNTN5 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54295665; called by muse, mutect2, varscan2
- COL4A5 | c.141G>A p.K47= | Splice Region (SNP) | VAF 27/57 reads (47%) | catalogued as rs1486934440, COSV60358831; called by muse, mutect2, varscan2
- CPAMD8 | c.665T>G p.M222R (on ENST00000651564; = p.M175R on NM_015692.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV52232903; called by muse, mutect2, varscan2
- CPED1 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV59999471; called by muse, mutect2, varscan2
- CPED1 | c.2929C>T p.H977Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.113); catalogued as COSV59999480; called by muse, mutect2, varscan2
- CR2 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV65506752; called by muse, mutect2, varscan2
- CSHL1 | c.410C>T p.S137L (on ENST00000309894 / NM_022581.3; = p.S43L on NM_001318.4) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as COSV51987646; called by muse, mutect2, varscan2
- CSMD2 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as rs760913752, COSV53896556; called by muse, mutect2, varscan2
- CUL9 | c.5503C>T p.H1835Y | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV52726948; called by muse, mutect2, varscan2
- CYP19A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 77/116 reads (66%) | catalogued as rs1359922150, COSV53058214; called by muse, mutect2, varscan2
- CYP2C8 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV64876511; called by muse, mutect2, varscan2
- DDX43 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 99/144 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV64836598; called by muse, mutect2, varscan2
- DENND5A | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60232582; called by muse, mutect2, varscan2
- DIDO1 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV56617465; called by muse, mutect2, varscan2
- DISC1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs776313827, COSV54403882; called by mutect2, varscan2
- DMTN | c.1144A>T p.M382L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56111764; called by muse, mutect2, varscan2
- DNAH3 | c.11864G>A p.W3955* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV54512418, COSV54540732; called by muse, mutect2, varscan2
- DNAH7 | c.11608C>T p.P3870S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56757720; called by muse, mutect2, varscan2
- DNAH8 | c.6031C>T p.L2011F | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59434836; called by muse, mutect2, varscan2
- DNTTIP2 | c.869A>C p.K290T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV63283825; called by muse, mutect2, varscan2
- DRD2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as rs370321461, COSV60756525; called by mutect2, varscan2
- DSCAM | c.4415G>A p.G1472E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68026958; called by muse, mutect2, varscan2
- E2F8 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as COSV51462571; called by muse, mutect2, varscan2
- ECD | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769492013, COSV65899078; called by muse, varscan2
- EEF1A2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as rs1214259914, COSV53205454; called by muse, varscan2
- EPHA1 | c.2085A>T p.R695= | Splice Region (SNP) | VAF 39/91 reads (43%) | catalogued as COSV51970001; called by muse, mutect2, varscan2
- EPHB1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs563780078, COSV67654835, COSV67657144; called by muse, mutect2, varscan2
- ERO1A | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV67470878; called by muse, mutect2, varscan2
- FAM110C | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV59655841; called by muse, mutect2, varscan2
- FAM135A | c.3037C>T p.P1013S (on ENST00000370479 / NM_001351599.1; = p.P800S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs764535352, COSV52049401; called by muse, mutect2, varscan2
- FAT3 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 144/421 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53092495, COSV53093860; called by muse, mutect2, varscan2
- FLG2 | c.3124G>A p.G1042R | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.056); catalogued as COSV66167527; called by muse, mutect2, varscan2
- FMNL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs777087549, COSV56491973; called by mutect2, varscan2
- FUT2 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs746750813, COSV101218169; called by muse, mutect2, varscan2
- FXR2 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100002259; called by muse, mutect2, varscan2
- GMDS | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs868623141, COSV66431278; called by muse, mutect2, varscan2
- GPLD1 | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 15/136 reads (11%) | catalogued as rs905869698, COSV100015639; called by muse, mutect2
- GPR6 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51571493; called by muse, mutect2, varscan2
- GPR61 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV68177395; called by muse, mutect2, varscan2
- GRAMD1B | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs759398423, COSV59202274, COSV59209107; called by muse, mutect2, varscan2
- GRM7 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63136700; called by muse, mutect2, varscan2
- GRTP1 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58149308; called by muse, mutect2, varscan2
- HEATR5B | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV51850985; called by muse, mutect2, varscan2
- HERC2 | c.11734A>C p.S3912R | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV55315496; called by muse, mutect2, varscan2
- HGF | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV55947178, COSV99736498; called by muse, mutect2, varscan2
- HGF | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV55947185; called by muse, varscan2
- HSPA12B | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV54766189; called by muse, mutect2, varscan2
- IDE | c.2794A>T p.T932S | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV56422397; called by muse, mutect2, varscan2
- IGSF10 | c.3850C>T p.P1284S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV56783232; called by muse, mutect2, varscan2
- INTS5 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57950868, COSV57953295; called by muse, mutect2, varscan2
- IPO5 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55153172; called by muse, mutect2
- ITIH1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746233954, COSV56259105; called by muse, mutect2, varscan2
- KIF2B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs868521567, COSV52128748; called by muse, mutect2, varscan2
- KLHL13 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as COSV53246050; called by muse, mutect2, varscan2
- KMT2D | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as rs772559303, COSV56424212, COSV56489850; called by muse, mutect2, varscan2
- LAMB4 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52716419; called by muse, mutect2, varscan2
- LDLRAD4 | c.393C>A p.I131= | Splice Region (SNP) | VAF 12/66 reads (18%) | catalogued as COSV63335461; called by muse, mutect2, varscan2
- LIPA | c.535A>T p.I179L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV51078415, COSV51081047; called by muse, mutect2, varscan2
- LLGL2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs761736519, COSV99390644; called by muse, mutect2, varscan2
- LRCH4 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764962596, COSV53824830; called by muse, mutect2, varscan2
- LRRC3 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV52399054; called by muse, mutect2, varscan2
- LRRC30 | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV67301519, COSV67301867; called by muse, mutect2, varscan2
- LRRIQ1 | c.3889C>T p.Q1297* | Nonsense Mutation (SNP) | VAF 59/185 reads (32%) | catalogued as COSV67828041; called by muse, mutect2, varscan2
- MALT1 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61934460; called by muse, mutect2, varscan2
- MEGF11 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56547589; called by muse, mutect2, varscan2
- MORC1 | c.2934T>G p.N978K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV51717003; called by muse, mutect2, varscan2
- MPP7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs767641039, COSV61731060; called by muse, mutect2, varscan2
- MRPL1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100214090; called by muse, mutect2
- MUC4 | c.15238G>A p.E5080K (on ENST00000463781 / NM_018406.7; = p.E844K on NM_004532.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.196); catalogued as COSV57773365; called by muse, mutect2, varscan2
- MYH7 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62517752; called by muse, mutect2, varscan2
- NAA25 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs774314377, COSV55703229; called by muse, mutect2, varscan2
- NEDD4L | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV56842611; called by muse, mutect2, varscan2
- NLRP1 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV52562205; called by muse, mutect2, varscan2
- NLRP13 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs544413027, COSV61619947; called by mutect2, varscan2
- NOTCH4 | c.4057G>A p.G1353R | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1301281297, COSV66679725; called by muse, mutect2
- NTSR1 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs773470664, COSV65138310; called by muse, mutect2, varscan2
- OR14A16 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62926345; called by muse, mutect2, varscan2
- OR1M1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV70036620; called by muse, mutect2
- OR2M3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs765663539, COSV71758955; called by muse, mutect2, varscan2
- OR4X2 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56582840; called by muse, mutect2, varscan2
- OR8B4 | c.486G>C p.M162I | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV62069523, COSV62070003; called by muse, mutect2, varscan2
- PAPSS2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63262964; called by muse, mutect2, varscan2
- PCDH15 | c.4123G>A p.G1375R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217511, COSV100225723, COSV57283134; called by muse, mutect2, varscan2
- PCDH15 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs370442031, COSV57263745; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, varscan2
- PCDHB5 | c.301C>G p.P101A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV50648787; called by muse, mutect2, varscan2
- PCDHGB4 | c.1982T>C p.V661A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.305); catalogued as COSV53920583; called by muse, mutect2, varscan2
- PEX5L | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99830230; called by muse, mutect2, varscan2
- PIP5K1B | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV55244949; called by muse, mutect2, varscan2
- PKP3 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.099); catalogued as COSV58986569; called by mutect2, varscan2
- PLEKHH2 | c.3219C>T p.S1073= | Splice Region (SNP) | VAF 22/77 reads (29%) | catalogued as rs113125573, COSV56751413; called by muse, mutect2, varscan2
- PPARG | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 112/335 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55141675; called by muse, mutect2, varscan2
- PRKCH | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.506); catalogued as rs901779406, COSV100273191, COSV60647023; called by muse, mutect2, varscan2
- PRLR | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51494293; called by muse, mutect2, varscan2
- PTPRN2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs748134802, COSV67030209; called by muse, mutect2, varscan2
- R3HDM2 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61286718; called by muse, mutect2, varscan2
- RAD54L2 | c.2529T>G p.D843E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56577795; called by muse, mutect2, varscan2
- RBM4B | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as COSV100026583; called by muse, mutect2, varscan2
- RFX6 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60584180; called by muse, mutect2, varscan2
- RTEL1 | c.3476T>C p.L1159P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV53926851; called by muse, mutect2, varscan2
- RYR2 | c.9467G>A p.G3156E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63675064; called by muse, mutect2
- SCAMP5 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs779571294, COSV62643210; called by muse, mutect2, varscan2
- SCN7A | c.4954C>T p.H1652Y | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.25); catalogued as COSV69270295; called by muse, mutect2, varscan2
- SERPING1 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV53541991; called by muse, mutect2, varscan2
- SGK2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58312606; called by muse, mutect2, varscan2
- SHROOM3 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56026051; called by muse, mutect2, varscan2
- SLC1A6 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.044); catalogued as rs865906356, COSV55669181; called by muse, mutect2, varscan2
- SLC4A10 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55771551, COSV55792767; called by mutect2, varscan2
- SLC6A2 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54915043; called by muse, mutect2, varscan2
- SLC7A14 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV51579905; called by muse, mutect2, varscan2
- SPAG17 | c.2820G>A p.W940* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as COSV60455830; called by muse, mutect2, varscan2
- SPHKAP | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV60868501; called by muse, mutect2, varscan2
- SPHKAP | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs148914025, COSV60868610; called by muse, mutect2, varscan2
- SPINK13 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV68241318; called by muse, mutect2, varscan2
- SPTB | c.3596C>T p.S1199F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101072471, COSV67631460; called by muse, mutect2, varscan2
- STAG1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52605691; called by muse, mutect2, varscan2
- STMN2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as COSV55218730; called by muse, mutect2
- SUOX | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV56267530; called by muse, mutect2, varscan2
- TAOK3 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs775947136, COSV66825205; called by muse, mutect2, varscan2
- TBC1D5 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.113); catalogued as COSV53752979; called by muse, mutect2, varscan2
- TDGF1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs201362162, COSV56125444; called by muse, mutect2, varscan2
- TICRR | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs575077664, COSV51539795; called by mutect2, varscan2
- TJP3 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV53661598; called by muse, mutect2
- TMC3 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV63922628; called by muse, mutect2, varscan2
- TMC5 | c.2068G>A p.E690K (on ENST00000396229 / NM_001105248.1; = p.E444K on NM_024780.5) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs201778492, COSV54900449; called by muse, mutect2, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as COSV60291749; called by muse, mutect2, varscan2
- TNRC6A | c.4288A>G p.R1430G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59362585; called by muse, mutect2, varscan2
- TRIM27 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 110/141 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV65873396; called by muse, mutect2, varscan2
- TRRAP | c.9212C>T p.P3071L (on ENST00000359863 / NM_001244580.1; = p.P3042L on NM_003496.3) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62841809; called by muse, mutect2, varscan2
- TTN | c.15106C>T p.R5036* (on ENST00000591111; = p.R4109* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs267599069, COSV59961885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP5 | c.2459T>A p.I820N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs771343069; called by muse, mutect2, varscan2
- USP32 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as rs576246445, COSV100342619, COSV56266315; called by muse, mutect2, varscan2
- USP34 | c.4772G>A p.G1591E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV68399757; called by muse, mutect2, varscan2
- WDR49 | c.1439C>T p.S480F (on ENST00000308378 / NM_001366158.1; = p.S821F on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); catalogued as COSV57705383; called by muse, varscan2
- WDR49 | c.1268C>T p.S423L (on ENST00000308378 / NM_001366158.1; = p.S764L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs747703419, COSV57705394, COSV57708425; called by muse, mutect2, varscan2
- XIRP2 | c.5569C>T p.R1857C (on ENST00000628543; = p.R2032C on NM_152381.6) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs547585778, COSV54687810; called by mutect2, varscan2
- YBX3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs760752611, COSV54384999; called by mutect2, varscan2
- ZDBF2 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as COSV65623519; called by muse, mutect2, varscan2
- ZDBF2 | c.5023C>T p.R1675* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | catalogued as rs374690917; called by muse, mutect2, varscan2
- ZDHHC11 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.125); catalogued as rs768718254, COSV52062495; called by muse, mutect2, varscan2
- ZEB2 | c.3562C>T p.H1188Y | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as COSV57954110; called by muse, mutect2, varscan2
- ZMYM3 | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs138633030, COSV58736912; called by muse, mutect2, varscan2
- ZNF560 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs545411097, COSV56866806; called by muse, mutect2, varscan2
- ZNF563 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.974); catalogued as rs868091481, COSV53370060; called by muse, mutect2, varscan2
- ZNF627 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.269); catalogued as COSV100741542; called by muse, mutect2, varscan2
- ZNF804A | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56441783; called by muse, mutect2, varscan2
- MUC2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- POM121C | c.2578C>T p.Q860* (on ENST00000607367; = p.Q618* on NM_001099415.3) | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 127/392 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRAV21 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ACSL1 | c.507T>C p.A169= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV55661543; called by muse, mutect2, varscan2
- AHNAK | c.17136C>T p.I5712= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs775743273, COSV57208568; called by muse, mutect2, varscan2
- ANGPT4 | c.1161C>T p.G387= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs780368430, COSV67921077; called by muse, mutect2, varscan2
- ANK1 | c.4368C>T p.I1456= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV55877479, COSV99224432; called by muse, mutect2, varscan2
- AP4B1 | c.988C>T p.L330= | Silent (SNP) | VAF 95/262 reads (36%) | catalogued as COSV56724081; called by muse, mutect2, varscan2
- BDP1 | c.2994C>T p.G998= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV62430334; called by muse, mutect2, varscan2
- BFSP1 | c.453C>T p.A151= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV64899789; called by muse, mutect2, varscan2
- BRF1 | c.873C>T p.P291= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100527900; called by muse, mutect2, varscan2
- BRPF3 | c.1110C>T p.L370= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV60206690; called by muse, mutect2, varscan2
- BTNL8 | c.1434C>T p.I478= | Silent (SNP) | VAF 30/45 reads (67%) | catalogued as COSV99180599; called by muse, mutect2, varscan2
- CATSPER4 | c.901C>T p.L301= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100128575; called by muse, mutect2, varscan2
- CCDC63 | c.441C>T p.P147= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV57527812; called by muse, varscan2
- CD109 | c.816C>T p.S272= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as rs998987931; called by muse, mutect2
- CEP250 | c.5316C>T p.L1772= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs775770000, COSV61168979; called by muse, mutect2, varscan2
- CIPC | c.471G>T p.L157= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV62376801; called by muse, mutect2, varscan2
- CLCNKA | c.1338C>T p.V446= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs1490606064, COSV58891011; called by muse, mutect2, varscan2
- COL3A1 | c.2703G>A p.K901= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV58584942; called by muse, varscan2
- CPLX4 | c.9C>T p.F3= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV55313306; called by muse, mutect2, varscan2
- CSMD1 | c.6150C>T p.L2050= (on ENST00000520002; = p.L2049= on NM_033225.6) | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV59301791; called by muse, mutect2, varscan2
- DES | c.1080C>T p.A360= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV64660077; called by muse, mutect2, varscan2
- DNM3 | c.1650C>G p.V550= (on ENST00000355305 / NM_001350206.2; = p.V540= on NM_015569.5) | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100798902, COSV62455460; called by muse, mutect2
- DST | c.17007C>T p.S5669= (on ENST00000361203 / NM_001374722.1; = p.S3366= on NM_015548.5) | Silent (SNP) | VAF 38/324 reads (12%) | catalogued as COSV55005437; called by muse, mutect2, varscan2
- EPHB2 | c.2364C>T p.I788= (on ENST00000400191 / NM_001309193.2; = p.I789= on NM_004442.7) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV65861283; called by muse, mutect2, varscan2
- ERCC1 | c.120C>T p.F40= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV50003903; called by muse, mutect2, varscan2
- ERGIC1 | c.693C>T p.F231= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV67127224; called by muse, mutect2, varscan2
- FER1L6 | c.3390C>T p.P1130= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as rs776469316, COSV67549016; called by muse, mutect2, varscan2
- FGFR4 | c.324C>T p.I108= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs781632034, COSV52800788; called by mutect2, varscan2
- FXR2 | c.1590G>A p.P530= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs779290681, COSV100002243; called by muse, mutect2, varscan2
- GCN1 | c.2922C>T p.S974= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs376436436; called by muse, mutect2, varscan2
- GLUD2 | c.1038G>A p.K346= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV60151570; called by muse, mutect2, varscan2
- GRINA | c.6C>T p.S2= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV57297265; called by muse, mutect2, varscan2
- GYG2 | c.291C>T p.I97= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV58549509; called by muse, mutect2, varscan2
- HPCA | c.243C>T p.D81= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs1226140032, COSV65102858; called by muse, mutect2, varscan2
- ITGAD | c.2047C>T p.L683= | Silent (SNP) | VAF 75/231 reads (32%) | catalogued as COSV66757348; called by muse, mutect2, varscan2
- ITIH1 | c.273C>T p.I91= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV56257017; called by muse, mutect2, varscan2
- ITIH2 | c.24C>T p.F8= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV64432577, COSV64434259; called by muse, mutect2, varscan2
- KCNV1 | c.1050C>T p.L350= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV52085396, COSV99819129; called by muse, mutect2, varscan2
- LEPR | c.921G>A p.Q307= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV60750610, COSV60750930; called by muse, mutect2, varscan2
- LETM1 | c.369C>T p.S123= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1429025118, COSV57099695; called by muse, mutect2, varscan2
- LRRC7 | c.2298A>T p.P766= (on ENST00000651989 / NM_001370785.2; = p.P733= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV50432024; called by muse, mutect2, varscan2
- LRRC8E | c.621G>A p.L207= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV60717401; called by mutect2, varscan2
- LYZL6 | c.366G>A p.G122= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs1159644647; called by muse, varscan2
- MACF1 | c.4237C>T p.L1413= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs771060389, COSV58366258; called by muse, mutect2, varscan2
- MAPKAP1 | c.1056C>T p.V352= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99785934; called by mutect2, varscan2
- MGAT4A | c.1461C>T p.F487= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1397149060, COSV53846201, COSV53849573; called by mutect2, varscan2
- MIER2 | c.543C>T p.S181= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs1045141437, COSV53394883; called by muse, varscan2
- MMP14 | c.384C>T p.I128= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV61287847, COSV61288343; called by muse, mutect2, varscan2
- MOV10L1 | c.2475C>T p.V825= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53169066; called by muse, mutect2, varscan2
- MRPL1 | c.498G>A p.E166= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs191548297, COSV100214086; called by muse, mutect2
- MUC3A | c.7869C>T p.I2623= | Silent (SNP) | VAF 97/487 reads (20%) | catalogued as COSV60213101; called by muse, mutect2, varscan2
- NFIX | c.273C>T p.F91= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV62175392; called by muse, varscan2
- NLRP3 | c.687G>A p.G229= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60220849; called by muse, mutect2, varscan2
- OR10Q1 | c.618C>T p.V206= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57470071; called by mutect2, varscan2
- OR1I1 | c.879G>A p.R293= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV52917648; called by muse, mutect2, varscan2
- OR51I1 | c.117C>T p.I39= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV66507316, COSV66507577; called by muse, mutect2, varscan2
- PCDHB3 | c.321G>A p.Q107= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV50567169; called by muse, mutect2, varscan2
- PEX5L | c.243C>T p.S81= | Silent (SNP) | VAF 52/186 reads (28%) | catalogued as COSV99830227; called by muse, mutect2, varscan2
- PI4KA | c.1332C>T p.L444= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV55407656; called by muse, mutect2, varscan2
- PIK3C2B | c.414C>T p.V138= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV65803492; called by muse, mutect2, varscan2
- PLVAP | c.963G>A p.A321= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs150210307; called by muse, mutect2, varscan2
- PLXND1 | c.2226C>T p.A742= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1478701141, COSV60711017; called by muse, mutect2, varscan2
- POMGNT2 | c.708C>T p.L236= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs367585873; called by muse, mutect2, varscan2
- PRAMEF18 | c.450C>T p.F150= | Silent (SNP) | VAF 73/402 reads (18%) | called by muse, mutect2, varscan2
- PRRC2A | c.5928C>T p.A1976= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV52989168; called by muse, mutect2, varscan2
- PTPN6 | c.336T>C p.H112= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs782589460, COSV59683828; called by muse, mutect2, varscan2
- RPL36AL | c.21C>T p.T7= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53562896; called by muse, mutect2, varscan2
- RRP36 | c.708G>A p.E236= | Silent (SNP) | VAF 189/241 reads (78%) | catalogued as COSV55063902, COSV55063974; called by muse, mutect2, varscan2
- RYR3 | c.14406A>G p.T4802= (on ENST00000389232; = p.T4803= on NM_001036.6) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV66782873; called by muse, mutect2, varscan2
- SCN10A | c.4374C>T p.I1458= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs1158599232, COSV101479389, COSV71860840; called by muse, mutect2, varscan2
- SH2B1 | c.624C>T p.T208= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs541383976, COSV59461599; called by muse, mutect2, varscan2
- SLC2A11 | c.1323C>T p.F441= (on ENST00000345044 / NM_001024938.4; = p.F448= on NM_030807.5) | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV55390575; called by muse, mutect2, varscan2
- SPTB | c.3597C>T p.S1199= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs745505216, COSV67632235; called by muse, mutect2, varscan2
- SPZ1 | c.150C>T p.L50= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV57062773; called by muse, mutect2, varscan2
- STMN2 | c.192C>T p.I64= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV55218719, COSV99626350; called by muse, mutect2
- TBXA2R | c.567C>T p.A189= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1321452377, COSV100916218, COSV64343345; called by muse, varscan2
- TENT4A | c.1581C>T p.A527= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs1439984715, COSV50094852; called by muse, mutect2, varscan2
- TEX47 | c.552C>T p.Y184= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as rs371691831; called by muse, mutect2, varscan2
- TKFC | c.1530G>A p.K510= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs765556317, COSV53650708, COSV53651370; called by muse, mutect2, varscan2
- TNC | c.3246G>T p.V1082= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100406443; called by muse, mutect2, varscan2
- TRAF1 | c.807C>T p.F269= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs200832066, COSV65868059; called by muse, mutect2, varscan2
- TRAV26-2 | c.192G>A p.V64= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- TSEN54 | c.687C>T p.S229= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV51345066; called by muse, mutect2, varscan2
- USH2A | c.12459C>A p.A4153= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56348516; called by mutect2, varscan2
- XPO7 | c.3144A>G p.R1048= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53012931; called by muse, mutect2, varscan2
- A1CF | c.100-6594A>C | Intron (SNP) | VAF 18/93 reads (19%) | catalogued as COSV99258243; called by muse, mutect2, varscan2
- EVL | c.352+12071C>T | Intron (SNP) | VAF 13/16 reads (81%) | catalogued as rs1253187345, COSV63005995; called by muse, mutect2, varscan2
- FMN1 | c.2044-1981del | Intron (DEL) | VAF 55/105 reads (52%) | catalogued as rs34563484; called by mutect2, pindel, varscan2
- FMN1 | c.2044-1982T>A | Intron (SNP) | VAF 64/96 reads (67%) | called by mutect2, varscan2
- GRIA4 | c.1269+1336G>A | Intron (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99235283; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.893G>A | RNA (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.892G>A | RNA (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- POLR2F | c.453-14962T>C | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SSPOP | n.15548_15551delinsA | RNA (DEL) | VAF 12/29 reads (41%) | called by pindel, varscan2*
